Somatic mutation profile of tumor specimen TCGA-EB-A85J-01A (aliquot TCGA-EB-A85J-01A-12D-A34U-08) from TCGA case TCGA-EB-A85J, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.4 years (24,263 days).
Specimen TCGA-EB-A85J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 834a576e-0e3a-4650-9a5a-9c5a598c57b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A85J-10B (Blood Derived Normal), aliquot TCGA-EB-A85J-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7be157c3-7cc7-4daf-b5fa-4aea5cc75347

The open-access MAF lists 461 somatic variants for this specimen: 309 protein-altering or splice-affecting, 145 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 275, Silent 145, Nonsense Mutation 29, RNA 3, Splice Region 3, Intron 2, Splice Site 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 53/147 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AADAC | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233000; called by muse, mutect2, varscan2
- ABL2 | c.2261C>T p.P754L (on ENST00000502732 / NM_007314.4; = p.P739L on NM_005158.5) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100772271; called by muse, mutect2, varscan2
- ACIN1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99398865; called by muse, mutect2, varscan2
- ACOXL | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV101093737; called by muse, mutect2, varscan2
- ADAM2 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99696472; called by muse, mutect2, varscan2
- ADAM29 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63665732; called by muse, mutect2, varscan2
- ADAM7 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV51536126; called by muse, mutect2, varscan2
- ADAMTS12 | c.2673G>A p.W891* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100710055, COSV61280121; called by muse, mutect2, varscan2
- ADAMTS7 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as rs753831522, COSV101182984, COSV101183194; called by muse, mutect2, varscan2
- ADGRG7 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1331300716, COSV99840373; called by muse, mutect2, varscan2
- ADORA3 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs1471388572, COSV99598566; called by mutect2, varscan2
- AFF1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV57125501; called by muse, mutect2, varscan2
- AGAP1 | c.2149G>A p.E717K (on ENST00000304032 / NM_001037131.3; = p.E664K on NM_014914.5) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1417650310, COSV100363362, COSV100365017; called by muse, mutect2, varscan2
- AGMO | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1043189372, COSV100693350, COSV61123336; called by muse, mutect2, varscan2
- AKAP6 | c.5861C>T p.S1954F | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs201421428, COSV99797328; called by muse, mutect2, varscan2
- AMZ1 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100406111; called by muse, mutect2, varscan2
- ANK3 | c.12745G>A p.E4249K (on ENST00000280772 / NM_001320874.2; = p.E873K on NM_001149.3) | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV55057682, COSV99777635; called by muse, mutect2, varscan2
- ANKRD2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100080651; called by muse, mutect2
- ANKRD30A | c.3889G>A p.E1297K (on ENST00000611781; = p.E1241K on NM_052997.2) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.12); catalogued as COSV64613017; called by muse, mutect2, varscan2
- AOC2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519860; called by muse, mutect2, varscan2
- ARAP2 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs201172273, COSV58282333, COSV58293236; called by muse, mutect2
- ARG1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99255948; called by mutect2, varscan2
- ARHGAP26 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV99188663; called by muse, mutect2, varscan2
- ARHGAP35 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as COSV101350595; called by muse, mutect2, varscan2
- ARHGEF5 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs749250615, COSV99282455; called by muse, mutect2, varscan2
- ARRDC2 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716539; called by muse, mutect2, varscan2
- ARSG | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV101477861; called by muse, mutect2
- ARSJ | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100192347, COSV59537225; called by muse, mutect2, varscan2
- ATP10B | c.4315G>A p.G1439R | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs376008088; called by muse, mutect2, varscan2
- ATP1A3 | c.2304C>T p.G768= (on ENST00000545399 / NM_001256214.2; = p.G755= on NM_152296.5) | Splice Region (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100131782; called by muse, mutect2, varscan2
- BNIP5 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101465095; called by muse, mutect2, varscan2
- BPIFB4 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1460071022, COSV100971379, COSV100971441; called by muse, mutect2, varscan2
- C12orf60 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99966761; called by muse, mutect2, varscan2
- C4BPB | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99699805, COSV99700183; called by muse, mutect2, varscan2
- C9orf131 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.234); catalogued as rs1475559020, COSV100397964, COSV56610626; called by muse, mutect2, varscan2
- CA6 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV101077282; called by muse, mutect2, varscan2
- CADM2 | c.1169G>A p.R390Q (on ENST00000407528 / NM_001167674.2; = p.R392Q on NM_153184.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67359256; called by muse, mutect2, varscan2
- CALHM4 | c.816G>A p.W272* (on ENST00000368596 / NM_001366078.1; = p.W86* on NM_153036.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100888826; called by muse, mutect2, varscan2
- CASKIN2 | c.3167G>A p.S1056N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100049994; called by muse, mutect2, varscan2
- CATSPERD | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58468007; called by muse, mutect2, varscan2
- CCDC71 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58910210; called by muse, mutect2, varscan2
- CD8B | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100514323; called by muse, mutect2, varscan2
- CDC20B | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99696370; called by muse, mutect2
- CDC25C | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086468; called by muse, mutect2, varscan2
- CDC37 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as COSV99705625; called by muse, mutect2
- CDH18 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1330301818, COSV99931176; called by muse, mutect2, varscan2
- CDH4 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777439660, COSV64649698; called by muse, mutect2, varscan2
- CDH4 | c.2698G>A p.G900R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848193; called by muse, mutect2, varscan2
- CDK19 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV100097801; called by muse, mutect2, varscan2
- CEACAM20 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV100386745; called by muse, mutect2, varscan2
- CEP126 | c.2401T>C p.C801R | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99680396; called by muse, mutect2
- CFHR5 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs373865739; called by muse, mutect2
- CHI3L1 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 40/96 reads (42%) | catalogued as rs868360435, COSV99703707; called by muse, mutect2, varscan2
- CHRNA2 | c.562A>C p.T188P | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99531805; called by muse, mutect2, varscan2
- CHRNA3 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100467662; called by muse, mutect2, varscan2
- CIC | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1171990316, COSV99358682; called by muse, mutect2, varscan2
- CLDN8 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99729601; called by muse, mutect2, varscan2
- CLEC3A | c.355G>A p.E119K (on ENST00000651443; = p.E110K on NM_005752.6) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- CLIC3 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV100860315; called by muse, mutect2
- CLPP | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1244525711, COSV99832123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV101483698, COSV71405742; called by muse, mutect2, varscan2
- CNBD1 | c.710G>A p.W237* | Nonsense Mutation (SNP) | VAF 25/112 reads (22%) | catalogued as rs757608759, COSV101575262; called by muse, mutect2, varscan2
- COL15A1 | c.1856G>A p.G619D | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100897285; called by muse, mutect2, varscan2
- COL28A1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV101258233; called by muse, mutect2, varscan2
- COL5A1 | c.4408C>T p.P1470S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100879287; called by muse, mutect2, varscan2
- CPT1C | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99773138; called by muse, mutect2, varscan2
- CR2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs909956111, COSV100889496; called by muse, mutect2, varscan2
- CREBBP | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV52120215; called by muse, mutect2, varscan2
- CRISP2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV59253357; called by muse, mutect2, varscan2
- CSMD1 | c.4442G>A p.R1481K (on ENST00000520002; = p.R1480K on NM_033225.6) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.982); catalogued as rs748250994, COSV100141706, COSV59295604; called by muse, mutect2, varscan2
- CSMD2 | c.3026A>G p.N1009S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99584262; called by muse, mutect2, varscan2
- CTTN | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452283742, COSV100096885, COSV100098187; called by muse, mutect2
- CWH43 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56935744; called by muse, mutect2, varscan2
- CYP3A43 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs767486696, COSV55937969; called by muse, mutect2, varscan2
- DMXL2 | c.5725C>T p.P1909S | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99195902; called by muse, mutect2, varscan2
- DNAH5 | c.13735C>T p.P4579S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs868145795, COSV54210768, COSV54240499; called by muse, mutect2, varscan2
- DNAH5 | c.8321G>A p.W2774* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV99443257; called by muse, mutect2, varscan2
- DNAH7 | c.4988C>T p.S1663F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56794937; called by muse, mutect2, varscan2
- DNAH9 | c.4299G>A p.M1433I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.381); catalogued as rs1471583348, COSV99303045; called by muse, mutect2, varscan2
- DNAH9 | c.11815G>A p.E3939K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350024, COSV99305877; called by muse, mutect2, varscan2
- DNM3 | c.1921G>A p.D641N (on ENST00000355305 / NM_001350206.2; = p.D635N on NM_015569.5) | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV100797700; called by muse, mutect2, varscan2
- DSCAML1 | c.1265C>T p.S422F (on ENST00000321322; = p.S362F on NM_020693.4) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); catalogued as COSV100354161; called by muse, mutect2, varscan2
- DSG3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs774278080, COSV99933569; called by muse, mutect2, varscan2
- DSG4 | c.2468G>A p.W823* | Nonsense Mutation (SNP) | VAF 7/122 reads (6%) | catalogued as CM115703, COSV100355069; called by muse, mutect2
- DYTN | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101510791; called by muse, mutect2
- ELAVL2 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs146832864, COSV99806413; called by muse, mutect2, varscan2
- EPHA6 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67569649, COSV67587325; called by muse, mutect2, varscan2
- ERI3 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs614447, COSV64830634; called by muse, mutect2, varscan2
- FAM209A | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as rs752842594, COSV54766038; called by muse, mutect2, varscan2
- FAM47A | c.2115G>A p.W705* | Nonsense Mutation (SNP) | VAF 43/115 reads (37%) | catalogued as COSV60500333; called by muse, mutect2, varscan2
- FAM47A | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1233627323, COSV100649652; called by muse, mutect2, varscan2
- FAM83F | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100328776; called by muse, mutect2, varscan2
- FBXO31 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as COSV61151514; called by muse, mutect2, varscan2
- FBXO38 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375017569; called by muse, mutect2, varscan2
- FBXO39 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs202030641, COSV100386080; called by muse, mutect2, varscan2
- FCRLA | c.914C>T p.P305L (on ENST00000367959; = p.P282L on NM_032738.4) | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99375574; called by muse, mutect2, varscan2
- FHL3 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV100885027; called by muse, mutect2, varscan2
- FHL5 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100459007; called by muse, mutect2, varscan2
- FKTN | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as COSV99795219; called by muse, mutect2, varscan2
- FLG | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.671); catalogued as COSV100910287, COSV64235705; called by muse, mutect2, varscan2
- FMO1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV61448431; called by muse, mutect2, varscan2
- FOXI1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775317199, COSV60389708; called by muse, mutect2, varscan2
- FSIP2 | c.17170G>A p.D5724N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV100553484; called by muse, mutect2, varscan2
- GABRB1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as rs1255847912, COSV54974161; called by muse, mutect2, varscan2
- GATA5 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV99435554; called by muse, mutect2, varscan2
- GBE1 | c.2005T>C p.F669L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV101450062, COSV70103504; called by muse, mutect2, varscan2
- GCNT1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100946377; called by muse, mutect2, varscan2
- GDPGP1 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV100291968; called by muse, mutect2, varscan2
- GPALPP1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100689074; called by muse, mutect2, varscan2
- GSTM4 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs751739487, COSV100263911; called by muse, mutect2, varscan2
- GTF2IRD1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs781884706, COSV99733839; called by muse, mutect2, varscan2
- GTF3C5 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.251); catalogued as COSV100565188; called by muse, mutect2, varscan2
- HDAC9 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV101285633, COSV67769809; called by mutect2, varscan2
- HECW2 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.094); catalogued as COSV99645348; called by muse, mutect2, varscan2
- IGFN1 | c.2356G>A p.G786R (on ENST00000295591 / NM_001367841.1; = p.G3243R on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1237855905, COSV55183628; called by muse, mutect2
- IKBKB | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747327806, COSV100645543; called by muse, mutect2, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, mutect2, varscan2
- IL7 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753164075, COSV55676535; called by muse, mutect2, varscan2
- INPP5A | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV61249513; called by muse, mutect2, varscan2
- IQGAP2 | c.1778G>A p.R593K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs755705908, COSV99166616; called by muse, mutect2, varscan2
- IRF8 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.103); catalogued as COSV99235936; called by muse, mutect2, varscan2
- ITPK1 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV99968092; called by muse, mutect2, varscan2
- KIAA0586 | c.964C>T p.P322S (on ENST00000619416 / NM_001244190.2; = p.P337S on NM_014749.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99707243; called by muse, mutect2, varscan2
- KLC1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99870992; called by muse, mutect2
- KLHL13 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53244193, COSV99450720; called by muse, mutect2, varscan2
- KLHL4 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs1476085711, COSV64144168; called by muse, mutect2, varscan2
- KLHL6 | c.761T>A p.L254H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100384179; called by muse, mutect2, varscan2
- KMT2E | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 30/135 reads (22%) | catalogued as COSV99995605; called by muse, mutect2, varscan2
- KRT13 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV55839031; called by muse, mutect2, varscan2
- KYNU | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as rs150018564, CM142921; called by muse, mutect2, varscan2
- LAMA1 | c.6584C>T p.P2195L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as rs768326863, COSV101054485; called by muse, mutect2, varscan2
- LAMA1 | c.6583C>T p.P2195S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs867060925, COSV67540648; called by muse, mutect2, varscan2
- LAMB3 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as rs1467836602, COSV100620004; called by muse, mutect2
- LCA5 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1394586743, COSV100878124, COSV100878270; called by muse, mutect2, varscan2
- LCOR | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV53715139, COSV53718587; called by muse, mutect2, varscan2
- LDB2 | c.833G>A p.S278N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100452295; called by muse, mutect2, varscan2
- LONRF2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101110802; called by muse, mutect2, varscan2
- LRFN2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599020, COSV57824981; called by muse, mutect2
- LRP1B | c.8992G>A p.E2998K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV67196287; called by muse, mutect2
- LRP1B | c.5663G>A p.G1888E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs754799609, COSV67212125; called by muse, mutect2, varscan2
- LRP1B | c.5255C>T p.S1752L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs761567956, COSV67215776; called by muse, mutect2, varscan2
- LRRC30 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV67301864; called by muse, mutect2, varscan2
- LVRN | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV63497610; called by muse, mutect2, varscan2
- MAGEE2 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.575); catalogued as rs1453669105, COSV64898283; called by muse, mutect2, varscan2
- MAML3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100504859; called by muse, mutect2, varscan2
- MAP2 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as rs1228272450, COSV99557158; called by muse, mutect2, varscan2
- MARCHF3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs143903354; called by muse, mutect2, varscan2
- MED23 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs924609151, COSV100644660; called by muse, mutect2, varscan2
- MMP25 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1004972120, COSV100339272; called by muse, mutect2, varscan2
- MON2 | c.2528T>A p.I843N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99741285; called by muse, mutect2, varscan2
- MSI2 | c.792C>T p.G264= | Splice Region (SNP) | VAF 40/130 reads (31%) | catalogued as COSV99401355; called by muse, mutect2, varscan2
- MUC16 | c.35783C>T p.S11928L | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV67453526; called by muse, mutect2
- MUC16 | c.4529G>A p.R1510K | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101197343; called by muse, mutect2, varscan2
- MUSK | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99503486; called by muse, mutect2, varscan2
- MYH1 | c.4193C>T p.A1398V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV99874545; called by muse, mutect2, varscan2
- MYO18B | c.7448C>T p.S2483F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100122485; called by muse, mutect2
- MYO1H | c.2776G>A p.V926M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775631343, COSV60445902; called by muse, mutect2, varscan2
- MYO9A | c.4727C>T p.S1576F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100612430; called by muse, mutect2, varscan2
- NAALADL1 | c.1061G>C p.R354P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100367849; called by muse, mutect2, varscan2
- NAV3 | c.6103C>T p.P2035S (on ENST00000397909 / NM_001024383.2; = p.P2013S on NM_014903.6) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57117615; called by muse, mutect2, varscan2
- NCOA6 | c.5239C>T p.P1747S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100749868; called by muse, mutect2, varscan2
- NCOR1 | c.6206C>T p.S2069F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV51970582; called by muse, mutect2, varscan2
- NMUR2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99676491, COSV99676881; called by muse, mutect2, varscan2
- NOTCH2 | c.1501A>G p.N501D | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV99862312; called by muse, mutect2, varscan2
- NRAP | c.3172G>A p.E1058K (on ENST00000359988 / NM_001322945.2; = p.E1023K on NM_006175.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV100748190; called by muse, mutect2, varscan2
- NTN4 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422633467, COSV59223078; called by muse, mutect2, varscan2
- NYAP2 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV99795395; called by muse, mutect2, varscan2
- OCM | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs749083347, COSV99631268; called by muse, mutect2, varscan2
- OGDHL | c.2954G>A p.R985K | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100934134; called by muse, mutect2, varscan2
- OR10A3 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100660199; called by muse, mutect2, varscan2
- OR10J3 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763795896, COSV59955373, COSV59955808; called by muse, mutect2, varscan2
- OR2A2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV68871596, COSV68871682; called by muse, mutect2, varscan2
- OR2B6 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.945); catalogued as COSV99773511; called by muse, mutect2, varscan2
- OR2L13 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 62/382 reads (16%) | catalogued as rs1277836729, COSV100813634; called by muse, mutect2, varscan2
- OR2L13 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV63548953, COSV63549512; called by muse, mutect2, varscan2
- OR2M5 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 19/578 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100822700; called by muse, mutect2
- OR4A47 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.172); catalogued as rs771715944, COSV71444957; called by muse, mutect2, varscan2
- OR4D5 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs866657750, COSV100189637; called by muse, mutect2
- OR4F6 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 49/191 reads (26%) | catalogued as rs368805567, COSV61026284; called by muse, varscan2
- OR4K2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53851775; called by muse, mutect2, varscan2
- OR5B2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs1379182703, COSV100222710; called by muse, mutect2, varscan2
- OR5K4 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV61584343; called by muse, mutect2, varscan2
- OR7G2 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as COSV100560259; called by muse, mutect2, varscan2
- OR8K1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV54402875; called by muse, mutect2, varscan2
- OR9A4 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101516321; called by muse, mutect2, varscan2
- OR9A4 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71885958, COSV71886030; called by muse, mutect2, varscan2
- OTUD7A | c.1741G>A p.E581K (on ENST00000307050 / NM_001382637.1; = p.E574K on NM_130901.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV61035901; called by muse, mutect2, varscan2
- PAPPA | c.4619C>T p.T1540I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100072549; called by muse, mutect2, varscan2
- PCDH17 | c.2558T>A p.I853K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.482); catalogued as COSV100931366; called by muse, mutect2, varscan2
- PCDH9 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117336; called by muse, mutect2, varscan2
- PCDHA3 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782306537, COSV63543579; called by muse, mutect2
- PCDHGA9 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1415465011, COSV53911980; called by muse, mutect2, varscan2
- PCDHGB2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99528118, COSV99548607; called by muse, mutect2
- PCLO | c.9700G>A p.E3234K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61623708; called by muse, mutect2
- PCSK5 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs34579561; called by muse, mutect2, varscan2
- PDLIM1 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100267584; called by muse, mutect2, varscan2
- PHF10 | c.1224C>T p.G408= | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as rs1562983686, COSV100179027; called by muse, mutect2, varscan2
- PHF3 | c.4202C>T p.S1401F | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50316655, COSV50325670, COSV50331070; called by muse, mutect2, varscan2
- PHKA1 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262254; called by muse, mutect2, varscan2
- PLB1 | c.697A>C p.S233R | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100577346; called by muse, mutect2, varscan2
- PLEKHG7 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs1179483150, COSV60822792; called by muse, mutect2
- PMFBP1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52827687, COSV99400330; called by muse, mutect2, varscan2
- POLE | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100264975; called by muse, mutect2, varscan2
- PRDM9 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57010376, COSV57010765; called by muse, mutect2, varscan2
- PREX2 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55763507; called by muse, mutect2, varscan2
- PREX2 | c.4669C>T p.R1557C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs752310428, COSV55749284; called by muse, mutect2, varscan2
- PRICKLE1 | c.2331T>A p.Y777* | Nonsense Mutation (SNP) | VAF 31/102 reads (30%) | catalogued as COSV100453309; called by muse, mutect2, varscan2
- PRKCZ | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV100423089; called by muse, mutect2, varscan2
- PRLHR | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV53303441; called by muse, mutect2, varscan2
- PROP1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV100383587; called by muse, mutect2, varscan2
- PRR16 | c.734C>T p.P245L (on ENST00000407149 / NM_001300783.2; = p.P222L on NM_016644.2) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65399517; called by muse, mutect2, varscan2
- PSG4 | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs557418562, COSV99735899; called by muse, varscan2
- PSG4 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as rs769695122, COSV54935756; called by muse, varscan2
- PSMF1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1455555429, COSV99850178; called by muse, mutect2, varscan2
- PTPRN2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV67049980; called by muse, mutect2, varscan2
- PTPRS | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.103); catalogued as COSV99508583; called by muse, mutect2, varscan2
- PUS7 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100708389; called by muse, mutect2
- PWWP3B | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as COSV100530826; called by muse, mutect2, varscan2
- RBM45 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99617408; called by muse, mutect2, varscan2
- RBM46 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs866164836, COSV55977357; called by muse, mutect2, varscan2
- RBM47 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV55930714; called by muse, mutect2, varscan2
- RGS13 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs368890453; called by muse, mutect2
- RNMT | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260534692, COSV100054370; called by muse, mutect2, varscan2
- RP1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55110595, COSV55111673; called by muse, mutect2, varscan2
- RTL1 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101128050; called by muse, mutect2, varscan2
- SAMD9 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs145665736; called by muse, mutect2
- SBF1 | c.3451C>T p.R1151C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754111011, COSV100817347; called by muse, mutect2, varscan2
- SEMA5A | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs772658212, COSV101226717; called by muse, mutect2, varscan2
- SEMG2 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1204674875, COSV65647272; called by muse, mutect2, varscan2
- SERPINA11 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs1349784373, COSV100593906; called by muse, mutect2, varscan2
- SERPINF1 | c.1095C>G p.N365K | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.83); catalogued as rs565464856, COSV99628622; called by muse, mutect2, varscan2
- SH3RF2 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756609677, COSV100767543; called by muse, mutect2, varscan2
- SHE | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1474953587, COSV59072638; called by muse, mutect2, varscan2
- SLC12A3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148945966, CM075012, COSV99344049; called by muse, mutect2, varscan2
- SLC12A8 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as COSV100101615; called by muse, mutect2, varscan2
- SLC26A7 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs970233650, COSV99402204; called by muse, mutect2, varscan2
- SLC45A1 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.322); catalogued as rs770086226, COSV57097356; called by muse, mutect2, varscan2
- SLC45A3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100901024; called by muse, mutect2, varscan2
- SLC4A1 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99292884; called by muse, mutect2, varscan2
- SLC5A8 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as COSV101610500; called by muse, mutect2
- SLC7A13 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.076); catalogued as COSV99878318; called by muse, mutect2, varscan2
- SMARCAD1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1313402430, COSV100758662; called by muse, mutect2, varscan2
- SNRPC | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99765117; called by muse, mutect2, varscan2
- SNX14 | c.1649T>C p.V550A (on ENST00000314673 / NM_001350535.1; = p.V497A on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100121364; called by muse, mutect2, varscan2
- SORBS1 | c.2692C>T p.R898W (on ENST00000361941 / NM_001034954.2; = p.R548W on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753771568, COSV99527179; called by muse, mutect2, varscan2
- SORL1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.47); catalogued as rs1053767134, COSV99492522; called by muse, mutect2, varscan2
- SPATA18 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99729615; called by muse, mutect2, varscan2
- SPEF2 | c.5398C>T p.Q1800* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100288618; called by muse, mutect2
- SPTB | c.4810G>A p.E1604K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV101071856; called by muse, mutect2, varscan2
- ST18 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144073708; called by muse, mutect2, varscan2
- STK10 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450564; called by muse, mutect2, varscan2
- STON2 | c.1055C>T p.S352F (on ENST00000649389 / NM_001366849.2; = p.S295F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.776); catalogued as COSV99964257; called by muse, mutect2, varscan2
- STRN | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 31/129 reads (24%) | catalogued as rs758893821, COSV55747440; called by muse, mutect2, varscan2
- SYTL5 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV99936735; called by muse, mutect2, varscan2
- TAP2 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145822869; called by muse, mutect2, varscan2
- TBX21 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as rs965811401, COSV51595325; called by muse, mutect2, varscan2
- TCF4 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs868162712, COSV100608746; called by muse, mutect2, varscan2
- TDO2 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs1301651886, COSV72233123; called by muse, mutect2, varscan2
- TEKT5 | c.543T>G p.N181K | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV51588999, COSV99295731; called by muse, mutect2, varscan2
- TENT5C | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as COSV65616617; called by muse, mutect2, varscan2
- TEX14 | c.3292G>A p.E1098K (on ENST00000240361 / NM_001201457.2; = p.E1092K on NM_198393.4) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.196); catalogued as COSV99541027; called by muse, mutect2, varscan2
- TFRC | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs746712619, COSV64054612; called by muse, mutect2, varscan2
- TINAG | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 15/175 reads (9%) | catalogued as rs1051484597, COSV99448091; called by muse, mutect2
- TIPARP | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); catalogued as COSV55814704, COSV99903613; called by muse, mutect2, varscan2
- TMEM37 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99191489; called by muse, mutect2, varscan2
- TMTC1 | c.1627C>T p.L543F (on ENST00000539277 / NM_001193451.2; = p.L435F on NM_175861.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as rs1301826580, COSV99758336; called by muse, mutect2, varscan2
- TNR | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as rs760449162, COSV54899028; called by muse, mutect2, varscan2
- TOM1L1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1218834646, COSV100779102; called by muse, mutect2, varscan2
- TOP2A | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101395961; called by muse, mutect2, varscan2
- TPRA1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952244; called by muse, mutect2, varscan2
- TPRG1 | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.584); catalogued as COSV100800076; called by muse, mutect2
- TRBC2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.361); catalogued as rs782542057; called by muse, mutect2, varscan2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TRIML2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.152); catalogued as COSV100455792, COSV58719366; called by muse, mutect2, varscan2
- TTN | c.64708G>A p.E21570K (on ENST00000591111; = p.E14146K on NM_003319.4) | Missense Mutation (SNP) | VAF 48/166 reads (29%) | PolyPhen probably damaging (0.994); catalogued as rs1215669622, COSV59975339; called by muse, mutect2, varscan2
- TTN | c.32026G>A p.E10676K (on ENST00000591111; = p.E9749K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | PolyPhen possibly damaging (0.503); catalogued as COSV60333947; called by muse, mutect2, varscan2
- TTN | c.9865C>T p.H3289Y (on ENST00000591111; = p.H3243Y on NM_003319.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | PolyPhen possibly damaging (0.67); catalogued as COSV100627604, COSV59863902; called by muse, mutect2
- TTN | c.8986G>A p.G2996S (on ENST00000591111; = p.G2950S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | PolyPhen probably damaging (0.911); catalogued as COSV100588757; called by muse, mutect2, varscan2
- UBE3A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV51669842; called by muse, mutect2, varscan2
- UGT2B17 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV100497140; called by muse, mutect2, varscan2
- UHRF1 | c.1645C>T p.P549S (on ENST00000612630 / NM_001290050.1; = p.P562S on NM_013282.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99503231; called by muse, mutect2, varscan2
- USH2A | c.14816C>T p.S4939L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs775948052, COSV100227474; called by muse, mutect2, varscan2
- USP33 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV62470753; called by muse, mutect2, varscan2
- VPS13A | c.3224T>C p.I1075T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100651890; called by muse, mutect2, varscan2
- VPS13B | c.8791C>T p.Q2931* | Nonsense Mutation (SNP) | VAF 7/124 reads (6%) | catalogued as COSV100660464; called by muse, mutect2
- VSTM4 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV60525209; called by muse, mutect2, varscan2
- WASHC2C | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV100313733, COSV60493457; called by muse, mutect2, varscan2
- WNT5B | c.80+1G>A p.X27_splice | Splice Site (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100148517; called by muse, mutect2, varscan2
- XAGE5 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs1177095923, COSV63568310; called by muse, mutect2, varscan2
- XIRP1 | c.622T>G p.S208A | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100453213; called by muse, mutect2, varscan2
- XIRP2 | c.6400C>T p.P2134S (on ENST00000628543; = p.P2309S on NM_152381.6) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV54704251; called by muse, mutect2, varscan2
- YTHDC1 | c.1291C>T p.P431S (on ENST00000344157 / NM_001031732.4; = p.P413S on NM_133370.4) | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100704557; called by muse, mutect2, varscan2
- ZBED9 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV101509065, COSV71729486; called by muse, mutect2, varscan2
- ZEB1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758828036, COSV58035973, COSV58045072; called by muse, mutect2, varscan2
- ZFAT | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs747833185, COSV64738099; called by muse, mutect2, varscan2
- ZFX | c.2285T>C p.F762S | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100457241; called by muse, mutect2, varscan2
- ZIM3 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs141519115, COSV99517472; called by muse, mutect2, varscan2
- ZNF208 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs202117924; called by muse, mutect2, varscan2
- ZNF563 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV99536335; called by muse, mutect2, varscan2
- ZNF658 | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1301607252; called by muse, mutect2
- ZNF711 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1170676581, COSV52151615; called by muse, mutect2, varscan2
- ZNF91 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100321856; called by muse, mutect2, varscan2
- ZNF92 | c.968G>A p.R323K (on ENST00000328747 / NM_152626.4; = p.R254K on NM_007139.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV100165623; called by muse, mutect2, varscan2
- GAS2L2 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- HRNR | c.5486C>T p.S1829F | Missense Mutation (SNP) | VAF 40/1162 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2
- IGHG1 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MRC1 | c.3065G>A p.W1022* | Nonsense Mutation (SNP) | VAF 107/385 reads (28%) | called by muse, mutect2, varscan2
- TRIM21 | c.408_408+7del p.X136_splice | Splice Site (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel*, varscan2*
- ABCC9 | c.3417C>T p.L1139= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs1489712694, COSV99683963; called by muse, mutect2, varscan2
- ABCD3 | c.366C>T p.F122= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs1462870194, COSV100238643; called by muse, mutect2, varscan2
- ACSM5 | c.1707G>A p.R569= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100088223; called by muse, mutect2, varscan2
- ADA2 | c.261C>T p.F87= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV52830582; called by muse, mutect2, varscan2
- ADAM23 | c.2460G>A p.K820= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100006245; called by muse, mutect2, varscan2
- ADAMTS16 | c.663G>A p.V221= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs868681599, COSV99939541; called by muse, mutect2, varscan2
- ADD2 | c.150G>A p.Q50= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs782169095, COSV100034358; called by muse, mutect2, varscan2
- ADGRF5 | c.3474G>A p.R1158= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1270527831, COSV51939029; called by muse, mutect2, varscan2
- ADGRF5 | c.1056G>A p.L352= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV51938404; called by muse, mutect2
- ADGRG6 | c.462G>A p.R154= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99745422; called by muse, mutect2, varscan2
- AGPAT3 | c.462C>T p.T154= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs143039422; called by muse, mutect2, varscan2
- AGPAT4 | c.306T>C p.F102= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100210807; called by muse, mutect2, varscan2
- AGXT2 | c.1065C>T p.G355= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV99183683; called by muse, mutect2, varscan2
- ANAPC7 | c.1542C>T p.I514= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV101482829; called by muse, mutect2, varscan2
- ANK1 | c.2181C>T p.V727= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99223511; called by muse, mutect2, varscan2
- ANKRD2 | c.1077C>T p.A359= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100080653; called by muse, mutect2, varscan2
- ARHGEF2 | c.321C>T p.S107= (on ENST00000361247 / NM_001162383.2; = p.S80= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as rs764870354, COSV100559861; called by muse, mutect2, varscan2
- BACH2 | c.615C>T p.A205= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV57587313; called by muse, mutect2, varscan2
- BCR | c.2376C>T p.S792= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1398610885, COSV100005772; called by muse, mutect2
- BRSK1 | c.675C>T p.L225= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs748366809, COSV58666310; called by muse, mutect2, varscan2
- BTNL9 | c.138C>T p.P46= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100576062; called by muse, mutect2, varscan2
- C6 | c.2244G>A p.G748= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV54704890; called by muse, mutect2, varscan2
- C6orf201 | c.168G>A p.P56= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs748978684, COSV60985757, COSV60988374; called by muse, mutect2, varscan2
- C9 | c.1446G>A p.V482= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV54675837, COSV99661504; called by muse, mutect2, varscan2
- CASR | c.408C>T p.P136= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as COSV99948325; called by muse, mutect2, varscan2
- CCDC180 | c.3642C>T p.I1214= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100826491; called by muse, mutect2
- CCDC60 | c.1188G>A p.E396= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100554436; called by muse, mutect2, varscan2
- CEP120 | c.2763C>T p.S921= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV100070683; called by muse, mutect2, varscan2
- CNTNAP2 | c.1227C>T p.L409= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs756898951, COSV62183326; called by muse, mutect2, varscan2
- COL4A5 | c.2973G>A p.G991= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV60372918; called by muse, mutect2
- COL6A5 | c.7210C>T p.L2404= (on ENST00000312481; = p.L2400= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99591510; called by muse, mutect2, varscan2
- CTR9 | c.843C>T p.F281= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100797210; called by muse, mutect2, varscan2
- CYBRD1 | c.600C>T p.F200= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs770358914, COSV100361338, COSV58426621; called by muse, mutect2, varscan2
- CYP2C18 | c.801C>T p.F267= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99608105; called by muse, mutect2, varscan2
- DCANP1 | c.489G>A p.K163= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV101538196; called by muse, mutect2, varscan2
- DLGAP2 | c.1953C>T p.S651= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101420956; called by muse, mutect2
- DNAJC1 | c.1608C>T p.I536= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs778766323, COSV100980958; called by muse, mutect2, varscan2
- DOCK9 | c.4143G>C p.S1381= (on ENST00000376460 / NM_001366676.2; = p.S1382= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs201530896, COSV100237360, COSV100238397; called by muse, mutect2, varscan2
- DSG1 | c.924C>T p.F308= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV57133841; called by muse, mutect2, varscan2
- EEF1AKNMT | c.909C>T p.F303= (on ENST00000361735 / NM_015935.5; = p.F217= on NM_014955.3) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1390126080, COSV62283443; called by muse, mutect2, varscan2
- EPHA8 | c.2676C>T p.L892= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs752672405, COSV51266491; called by muse, mutect2, varscan2
- EPX | c.1632G>A p.L544= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99836135; called by muse, mutect2, varscan2
- ERICH3 | c.1230G>A p.P410= | Silent (SNP) | VAF 44/197 reads (22%) | catalogued as rs375773806; called by muse, mutect2, varscan2
- FAM135B | c.489G>A p.V163= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV50524834; called by muse, mutect2, varscan2
- FAM90A1 | c.213G>A p.P71= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs376865646; called by muse, mutect2, varscan2
- FCGBP | c.10104C>T p.L3368= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- FER1L6 | c.3633T>C p.I1211= | Silent (SNP) | VAF 106/230 reads (46%) | catalogued as COSV101205248; called by muse, mutect2, varscan2
- FLCN | c.1209C>T p.I403= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99549993; called by muse, mutect2, varscan2
- FSHR | c.1263T>A p.V421= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100436308; called by muse, mutect2, varscan2
- GABRA3 | c.279G>A p.V93= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV64804443; called by muse, mutect2, varscan2
- GALNT15 | c.1515C>T p.F505= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as COSV100327183, COSV60220174; called by muse, mutect2, varscan2
- GLI1 | c.831G>A p.R277= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV57362536, COSV57365455; called by muse, mutect2, varscan2
- GLYATL2 | c.873G>A p.K291= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV54849034, COSV54849108; called by muse, mutect2, varscan2
- GRIN2B | c.4062C>T p.S1354= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV101662853; called by muse, mutect2, varscan2
- H1-5 | c.405G>A p.A135= | Silent (SNP) | VAF 72/368 reads (20%) | catalogued as rs1403695012, COSV100137605, COSV100138072, COSV58900805; called by muse, mutect2, varscan2
- HPCAL4 | c.6G>A p.G2= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100864740; called by muse, mutect2
- HS6ST3 | c.1017G>A p.Q339= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100939890, COSV65013146, COSV65015211; called by muse, mutect2
- IGLL5 | c.342C>T p.N114= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV101138565; called by muse, mutect2, varscan2
- IKBKB | c.1596C>T p.L532= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV100645545; called by muse, mutect2, varscan2
- KCNH1 | c.780C>T p.I260= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV99656670; called by muse, mutect2, varscan2
- KLHL13 | c.21G>A p.T7= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1214866972, COSV99450724; called by muse, mutect2, varscan2
- KLHL22 | c.1050C>T p.F350= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs774571360, COSV61020354; called by muse, mutect2, varscan2
- KRT33B | c.511C>T p.L171= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52442452; called by muse, mutect2
- LRG1 | c.138C>T p.F46= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100014563; called by muse, mutect2, varscan2
- LRIT1 | c.747G>A p.R249= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100927971; called by muse, mutect2, varscan2
- LRRC3B | c.525C>T p.S175= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs772377248, COSV101185615, COSV101185625; called by muse, mutect2, varscan2
- MAP3K14 | c.1116C>T p.P372= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100766352; called by muse, mutect2, varscan2
- ME1 | c.102G>A p.E34= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV63840920; called by muse, mutect2, varscan2
- MIOX | c.165C>T p.F55= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs748358902, COSV53312862; called by muse, mutect2, varscan2
- MPP4 | c.1644G>A p.S548= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs750057491, COSV53804797; called by muse, mutect2, varscan2
- MRGPRX2 | c.303C>T p.F101= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV61673820; called by muse, mutect2
- MTUS2 | c.1719C>T p.P573= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV101462012; called by muse, mutect2, varscan2
- MUC16 | c.33508C>T p.L11170= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV101197342, COSV67447269; called by muse, mutect2, varscan2
- MYH4 | c.3468A>G p.E1156= | Silent (SNP) | VAF 36/186 reads (19%) | catalogued as COSV99700092; called by muse, mutect2, varscan2
- MYO1E | c.1506C>T p.F502= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs913508027, COSV55682755; called by muse, mutect2, varscan2
- MZF1 | c.39C>T p.P13= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99284966; called by muse, mutect2, varscan2
- NAALADL2 | c.258C>T p.S86= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV70794503; called by muse, mutect2, varscan2
- NAV1 | c.2262C>T p.S754= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99818011; called by muse, mutect2, varscan2
- NCOA6 | c.3516C>T p.P1172= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100749869; called by muse, mutect2
- NEXMIF | c.303C>T p.L101= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99279257; called by muse, mutect2, varscan2
- NPHS1 | c.261G>A p.G87= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62287631; called by muse, mutect2, varscan2
- NPNT | c.1668G>A p.L556= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59752357; called by muse, mutect2, varscan2
- NR6A1 | c.468C>T p.I156= (on ENST00000487099 / NM_033334.4; = p.I152= on NM_001489.5) | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV100748383; called by muse, mutect2, varscan2
- OR10H1 | c.84C>T p.F28= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as COSV58472244; called by muse, mutect2, varscan2
- OR10P1 | c.36C>T p.F12= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV100548086; called by muse, mutect2, varscan2
- OR1D5 | c.531C>T p.L177= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs1205724782, COSV101643401; called by muse, mutect2, varscan2
- OR2F1 | c.705G>A p.K235= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV101231280, COSV67331715; called by muse, mutect2, varscan2
- OR2L8 | c.180C>T p.F60= | Silent (SNP) | VAF 298/539 reads (55%) | catalogued as COSV61728485; called by muse, mutect2, varscan2
- OR4K2 | c.162C>T p.H54= | Silent (SNP) | VAF 53/449 reads (12%) | catalogued as COSV100063901, COSV53851601; called by muse, mutect2, varscan2
- OR4K5 | c.870G>A p.R290= | Silent (SNP) | VAF 46/385 reads (12%) | catalogued as COSV60002477; called by muse, mutect2, varscan2
- OR51E1 | c.483C>G p.P161= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV101211433; called by muse, mutect2, varscan2
- OR52B6 | c.120G>A p.L40= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV61448040; called by muse, mutect2
- OR5M10 | c.660C>T p.F220= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV73242443; called by muse, mutect2, varscan2
- OR8B12 | c.903G>A p.R301= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100172935, COSV60910789; called by muse, mutect2, varscan2
- OTUD7A | c.618G>A p.G206= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100191640; called by muse, mutect2, varscan2
- OVGP1 | c.1143C>T p.I381= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100867920; called by muse, mutect2, varscan2
- PCDH10 | c.756A>G p.Q252= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs1385056501, COSV52089701; called by muse, mutect2, varscan2
- PCNX4 | c.834C>T p.F278= (on ENST00000406854 / NM_001330177.2; = p.F44= on NM_022495.5) | Silent (SNP) | VAF 52/186 reads (28%) | catalogued as COSV100469644; called by muse, mutect2, varscan2
- PIP5K1B | c.936G>A p.Q312= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99597704; called by muse, mutect2, varscan2
- PKLR | c.807C>T p.V269= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100712753; called by muse, mutect2, varscan2
- PKP3 | c.2061G>A p.R687= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100229699, COSV58986560; called by mutect2, varscan2
- PLCB4 | c.2940G>A p.E980= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV53802631; called by muse, mutect2, varscan2
- PLXDC1 | c.495C>T p.I165= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV100194718, COSV59549320; called by muse, mutect2
- PRAMEF20 | c.555G>A p.L185= | Silent (SNP) | VAF 133/472 reads (28%) | called by muse, mutect2, varscan2
- PRPF4B | c.1953C>T p.A651= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs145998699; called by muse, mutect2, varscan2
- PRPF8 | c.384C>T p.F128= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs759914879, COSV100516990, COSV59264658; called by muse, mutect2, varscan2
- PRPS1L1 | c.372C>T p.I124= | Silent (SNP) | VAF 10/173 reads (6%) | catalogued as rs1476784445, COSV72650017; called by muse, mutect2
- PSG2 | c.697C>T p.L233= | Silent (SNP) | VAF 101/394 reads (26%) | catalogued as COSV100283294; called by muse, mutect2, varscan2
- RALGAPB | c.810C>T p.I270= | Silent (SNP) | VAF 80/184 reads (43%) | catalogued as COSV53442787; called by muse, mutect2, varscan2
- RCAN2 | c.483C>T p.V161= | Silent (SNP) | VAF 31/214 reads (14%) | catalogued as rs201355064, COSV57820219; called by muse, mutect2, varscan2
- RNF128 | c.897C>T p.F299= (on ENST00000255499 / NM_194463.2; = p.F273= on NM_024539.3) | Silent (SNP) | VAF 5/115 reads (4%) | called by muse, mutect2
- SART3 | c.1161C>T p.N387= (on ENST00000228284; = p.N369= on NM_014706.4) | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV99933768; called by muse, mutect2, varscan2
- SATB2 | c.1192C>T p.L398= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99610383; called by muse, mutect2, varscan2
- SCRN1 | c.459C>T p.F153= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV99620616; called by muse, mutect2, varscan2
- SEC31B | c.2382C>T p.P794= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100947174; called by mutect2, varscan2
- SFRP5 | c.714G>A p.K238= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV56603718; called by muse, mutect2, varscan2
- SI | c.324C>T p.F108= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV52300443; called by muse, mutect2, varscan2
- SKAP1 | c.195G>A p.Q65= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV61149968; called by muse, mutect2, varscan2
- SLC26A8 | c.456C>T p.F152= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV100839357; called by muse, mutect2, varscan2
- SOX7 | c.501C>T p.P167= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs563553563, COSV58731690; called by muse, mutect2, varscan2
- SPATA31E1 | c.841C>T p.L281= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs773343078, COSV100349699; called by muse, mutect2, varscan2
- SPTA1 | c.2469G>A p.K823= | Silent (SNP) | VAF 71/170 reads (42%) | catalogued as rs756795170, COSV100934009, COSV100934252; called by muse, mutect2, varscan2
- SRGAP3 | c.1569C>T p.V523= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as rs753327611, COSV100840598; called by muse, mutect2, varscan2
- STAB1 | c.1014G>A p.G338= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100400928; called by muse, mutect2, varscan2
- STK31 | c.2385C>T p.F795= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100669036; called by muse, mutect2, varscan2
- SV2A | c.15C>T p.F5= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100974940; called by muse, mutect2, varscan2
- SYT2 | c.399G>A p.E133= | Silent (SNP) | VAF 9/149 reads (6%) | catalogued as COSV100937115; called by muse, mutect2
- TACC2 | c.3816G>A p.G1272= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100551220; called by muse, mutect2, varscan2
- TAS2R38 | c.264G>A p.L88= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV71885326; called by muse, mutect2, varscan2
- TBC1D17 | c.966C>T p.F322= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV55577443; called by muse, mutect2, varscan2
- TEX26 | c.600C>T p.F200= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV100993990; called by muse, mutect2, varscan2
- THBS4 | c.321G>A p.G107= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as rs770357704, COSV100644158; called by muse, mutect2, varscan2
- TLR4 | c.2082G>A p.K694= (on ENST00000355622 / NM_138554.5; = p.K654= on NM_003266.4) | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV62924302; called by muse, mutect2, varscan2
- TPTE | c.300C>T p.F100= (on ENST00000618007 / NM_199261.4; = p.F82= on NM_199259.4) | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs1393540247; called by muse, mutect2
- TRAV9-2 | c.210G>A p.T70= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs554640975; called by muse, mutect2, varscan2
- TRPV6 | c.447C>T p.P149= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV100844027; called by muse, mutect2, varscan2
- TSGA10IP | c.450C>T p.S150= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV73245436; called by muse, mutect2
- TTC17 | c.3426G>A p.*1142= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as rs957626725, COSV99234499; called by muse, mutect2
- UGT1A1 | c.594C>T p.S198= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as rs199675631, COSV100529227; called by muse, mutect2, varscan2
- VCX | c.117C>A p.A39= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100406154; called by muse, mutect2, varscan2
- VIL1 | c.1473C>T p.I491= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs749111220, COSV50285307, COSV99945092; called by muse, mutect2, varscan2
- VSTM1 | c.417C>T p.A139= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100618637; called by muse, mutect2, varscan2
- VSTM4 | c.651G>A p.V217= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100251108; called by muse, mutect2, varscan2
- WASHC2C | c.3384C>T p.D1128= (on ENST00000336378; = p.D1107= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- ZNF800 | c.1404C>T p.G468= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV56176273; called by muse, mutect2, varscan2
- DPP6 | c.627+21028C>T | Intron (SNP) | VAF 12/80 reads (15%) | catalogued as rs1324411787, COSV100122398; called by muse, mutect2, varscan2
- DSCR4 | n.378G>A | RNA (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100076946; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847773 G>A | 5'Flank (SNP) | VAF 34/476 reads (7%) | called by muse, mutect2
- PDP1 | c.-159G>A | 5'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs771703282, COSV99891777; called by muse, varscan2
- SNORD115-10 | n.60C>T | RNA (SNP) | VAF 115/488 reads (24%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2686C>T | RNA (SNP) | VAF 8/47 reads (17%) | catalogued as rs369606748; called by muse, mutect2, varscan2
- VGLL4 | c.64+31662C>T | Intron (SNP) | VAF 13/44 reads (30%) | catalogued as rs1433959633, COSV99809037; called by muse, mutect2, varscan2
